Somatic mutation profile of tumor specimen C3N-00651-54 (aliquot CPT0437950001) from CPTAC case C3N-00651, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 60.7 years (22,186 days).
Specimen C3N-00651-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6ff3ec6-b199-45df-8df5-c43d86f5e38e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00651-50 (Buccal Cell Normal), aliquot CPT0435060001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f955e30-d4d7-4874-84d4-2548be630011

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WT1 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 46/356 reads (13%) | catalogued as rs1423753702, CM971594, COSV60067818, COSV60068249, COSV60071382, COSV60073329, COSV60074859, COSV60075137; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDH12 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs143124599, COSV66443827; called by muse, mutect2
- GRIN2A | c.2984C>T p.T995M | Missense Mutation (SNP) | VAF 26/484 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs777687136, COSV58031170, COSV58061084; called by muse, mutect2
- ANK2 | c.3739A>G p.M1247V | Missense Mutation (SNP) | VAF 19/344 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.036); called by muse, mutect2
- PML | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 28/362 reads (8%) | called by muse, mutect2
- POM121L2 | c.1936G>T p.V646L | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.377); called by muse, mutect2
